CGCI case BLGSP-71-19-00116 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8c9c36bd-ca35-4158-ae79-b317d3a61128

Demographics
Sex at birth: male; Race: black or african american; Age at index: 9 years.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Intra-abdominal lymph nodes; Classification of tumor: primary; Age at diagnosis: 9.4 years (3,425 days); Year of diagnosis: 2000; Method of diagnosis: Biopsy; Ann Arbor pathologic stage: Stage III; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 4,438 days (12.2 years); Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Sporadic, pediatric; Max tumor bulk site: Other; Sites of involvement: Peritoneum, NOS / Abdomen.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Mesenteric; Tumor largest dimension diameter: 8 cm.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 4,438 days (12.2 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 0.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Positive.
- Lactate Dehydrogenase 1022.
- Epstein-Barr Virus: Positive.

Other clinical attributes
- Day 0: Weight: 38 kg; Height: 134 cm; BMI: 21.2.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-19-00116-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node(s) Mesenteric; Preservation method: Frozen; Days to sample procurement: 3 days; Method of sample procurement: Excisional Biopsy; Tissue collection type: Retrospective.
  Slide BLGSP-71-19-00116-01A-01-S2-HE: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 3; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
  Slide BLGSP-71-19-00116-01A-01-S1-HE: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
- Sample BLGSP-71-19-00116-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample BLGSP-71-19-00116-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Lymphocytes; Preservation method: Frozen; Days to sample procurement: 3,062 days (8.4 years); Method of sample procurement: Blood Draw; Tissue collection type: Retrospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: Yes; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Small, non-cleaved cell, Burkitt; Extranodal site involvement: 2; Extranodal involvment other: peritoneal fluid and intra-abdominal; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: Fine needle biopsy; Lymph nodes examined: No.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Tests performed: LDH level: 1022.
